Somatic mutation profile of tumor specimen MP2PRT-PAUHMP-TBP1-A (aliquot MP2PRT-PAUHMP-TBP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUHMP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,378 days).
Specimen MP2PRT-PAUHMP-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948f842e-cb70-40bc-82a1-46c69449ea8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUHMP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUHMP-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/148b1867-db4c-4040-9d0e-f15d204dca84

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF16 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 153/764 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as rs368261361; called by muse, mutect2, varscan2
- NEB | c.11429A>C p.K3810T | Missense Mutation (SNP) | VAF 112/397 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs1362955515, COSV51420130; called by muse, mutect2, varscan2
- RBM20 | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 26/508 reads (5%) | catalogued as COSV65706160; called by muse, mutect2
- TET3 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 149/705 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as rs1436733238, COSV101327656; called by muse, mutect2, varscan2
- GPHN | c.976A>G p.M326V (on ENST00000315266 / NM_001377519.1; = p.M359V on NM_020806.5) | Missense Mutation (SNP) | VAF 37/491 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2
- ZNF324 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 41/716 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2
- IGLV3-27 | c.279C>T p.I93= | Silent (SNP) | VAF 32/550 reads (6%) | called by muse, mutect2
- PTPRN2 | c.312G>A p.V104= | Silent (SNP) | VAF 32/502 reads (6%) | called by muse, mutect2
- SDR16C5 | c.156C>T p.L52= | Silent (SNP) | VAF 102/524 reads (19%) | catalogued as rs1240197716, COSV58125371; called by muse, mutect2, varscan2
- TEX15 | c.4989G>A p.L1663= (on ENST00000256246; = p.L2046= on NM_001350162.2) | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2
